Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5970, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5970-01A (Primary Tumor).

[page 1 of 4]
DIAGNOSIS

(A) RIGHT CHEEK LESION:

SQUAMOUS CARCINOMA, WELL DIFFERENTATED, TRANSECTED.

(B) TOTAL GLOSSECTOMY:

INVASIVE SQUAMOUS CARCINOMA -- Moderately differentiated

Tumor Features:

Gross: Ulcerating
Size: 4.0 cm in largest dimension
Invasion: Present, depth 2.0 cm
Tumor Border: Infiltrative with thick cords > 4 cells
Perineural and intraneural Invasion: Present
Vascular Invasion: Absent
Lymphocyte Infiltration: Moderate
Margins: free of tumor

(C) BILATERAL NECK DISSECTION Right neck dissection

METASTATIC CARCINOMA IN 2 OF 25 LYMPH NODES (Level II, Level III)

Level I:

No lymph node present

Level II:

Positive Nodes = 1

Total Nodes = 3

Metastasis size = 0.3 cm

Extracapsular Extension: Present, minimal, less than or equal to 1 mm

Level III:

Positive Nodes = 1

Total Nodes = 2

Metastasis size = 1.2 cm

Extracapsular Extension: Present, extensive, greater than 1 mm

Level IV:

Positive Nodes = 0

Total Nodes = 15

Level V:

Positive Nodes = 0

Total Nodes = 5

Left neck dissection

[page 2 of 4]
METASTATIC CARCINOMA IN 9 OF 25 LYMPH NODES (Level I, Level II, Level III, Level IV, Level V)

Level I:

Positive Nodes = 1
Total Nodes = 4
Metastasis size = 0.5 cm
Extracapsular Extension: absent

Level II:

Positive Nodes = 1
Total Nodes = 4
Metastasis size = 0.8 cm
Extracapsular Extension: Present, extensive, greater than 1 mm

Level III:

Positive Nodes = 1 (see comment)
Total Nodes = 1
Metastasis size = 1.8 cm
Extracapsular Extension: Present, extensive, greater than 1 mm

Level IV:

Positive Nodes = 4
Total Nodes = 6
Metastasis size = 0.8 cm
Extracapsular Extension: Present, extensive, greater than 1 mm

Level V:

Positive Nodes = 2
Total Nodes = 10
Metastasis size = 0.2 cm
Extracapsular Extension: absent

Right and left submandibular glands, no tumor present

(D) RIGHT CHEEK LESION:

INVASIVE SQUAMOUS CARCINOMA -- Moderately differentiated

Tumor Features:

Gross: Exophytic
Size: 1.8 cm in largest dimension
Invasion: Present, depth 0.6 cm
Tumor Border: Infiltrative with thick cords > 4 cells
Perineural Invasion: Absent
Vascular Invasion: Absent
Lymphocyte Infiltration: Mild

Mucosal Margin: Negative for invasive carcinoma

Deep Margin: Negative for invasive carcinoma

[page 3 of 4]
GROSS DESCRIPTION

(A) RIGHT CHEEK LESION – A fragment of tan-white tissue (1.1 x 0.7 x 0.3 cm) bisected and entirely submitted for frozen section diagnosis in A. [REDACTED]
*FS/DX: KERATOCYTIC LESION, LIKELY WELL-DIFFERENTIATED SQUAMOUS CELL CARCINOMA PRESENT AT DEEP TISSUE EDGE [REDACTED]
(B) TOTAL GLOSSECTOMY – The specimen consists of a tongue (8.5 x 6.0 x 5.5 cm) with centrally located partially fungating, partially ulcerated tan-white circumscribed lesion (4.0 x 3.0 x 3.0 cm). The specimen is submitted in representative section B1-B17, tumor with adjacent tissue submitted from the anterior towards the posterior aspect. [REDACTED]
(C) BILATERAL NECK DISSECTION, LONG STITCH ON LEFT LEVEL I - A bilateral neck dissection specimen that contains multiple lymph nodes. The largest nodes are found within the left level III and are 3.0 x 2.8 x 2.0 cm and 2.8 x 1.8 x 1.6 cm. The right and left submandibular glands are grossly unremarkable.

SECTION CODE: C1, three possible lymph nodes from right level 1; (C2 and C3, right level 2) C2, right submandibular gland; C3, four possible lymph nodes; (C4, C5, right level 3) C4, three possible lymph nodes; C5, one possible lymph node, bisected; (C6-C8, right level 4) C6-C8, five possible lymph nodes each; C9, right level 5, five possible lymph nodes; C10, left level 1, four possible lymph nodes; (C11-C15, left level 2) C11, left submandibular gland; C12, two possible lymph nodes; C13-C15, one possible lymph node each, bisected; (C16, C17, left level 3) C16, representative section of grossly positive node; C17, representative section of second grossly positive node; (C18-C20, left level 4) C18, four possible lymph nodes; C19, C20, one possible lymph node each, bisected; (C21-C23, left level 5); C21, five possible lymph nodes; C22, four possible lymph nodes; C23, two possible lymph nodes. [REDACTED]

(D) RIGHT CHEEK LESION, DOUBLE STITCH ANTERIOR, SINGLE STITCH SUPERIOR – The specimen consists of an elliptical piece of tan-beige skin with subcutaneous tissue (3.7 x 3.1 x 1.4 cm).
There is a centrally located tan-white nodular, fairly well-circumscribe lesion (1.8 x 1.5 x 1.1 cm). It is located 0.5 cm from inferior and superior margins. The specimen is oriented.

INK CODE: Inferior aspect from anterior-to-posterior – red; superior aspect from posterior-to-anterior – blue; deep – black.

SECTION CODE: D1-D5, submitted for frozen section, D1 anterior superior margin en face; D2, posterior superior margin en face; D3, posterior anterior margin en face; D4, anterior margin en face; D5, full-thickness of tumor and deep margin. D6-D11, the remaining portion of the specimen is submitted entirely going from anterior towards posterior aspect.

*FS/DX: PERIPHERAL AND DEEP MARGINS, NEGATIVE FOR TUMOR. TUMOR PRESENT. [REDACTED]

CLINICAL HISTORY

Left oral tongue cancer

SNOMED CODES

T-51300, M-43000, T-53000, M-80703, M-43000,T-C4200, M-80706

[page 4 of 4]
Entire report and diagnosis completed by:

Surgical Pathology Report	Page 4 of 4
File under: Pathology	

Source: NCI Genomic Data Commons file 1a562274-38b7-4e80-bcc0-2c9f1078d6ef (TCGA-CV-5970.A9CF8A6C-5A75-4FFC-829C-C30859A4EB8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).